Gene-level copy-number profile of tumor specimen C3L-06212-01 from CPTAC case C3L-06212, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 72.2 years (26,356 days).
Specimen C3L-06212-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8f6087ea-4272-43a3-afda-5b70fd42da84.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06212-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,785 have no estimate.
https://portal.gdc.cancer.gov/files/edbe2505-a0aa-4ded-abc1-d72633dfde29

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 376; copy number 1: 19,157; copy number 2: 29,153; copy number 3: 7,841; copy number 4: 1,323; copy number 5: 179; copy number 6: 381; copy number 7: 221; copy number 8: 33; copy number 9: 18; copy number 10: 8; copy number 11: 3; copy number 12: 15; copy number 13: 4; copy number 14: 107; copy number 21: 4; copy number 22: 2; copy number 24: 1; copy number 25: 1; copy number 26: 11.

Homozygous deletions (total copy number 0; autosomes only): 56 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,595,216–143,769,083, 9 genes: NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P.
- chr1:143,811,359–144,068,350, 9 genes: AC239798.1, AC239798.2, FCGR1CP, H2BP2, H3-2, AC246680.1, RPL22P5, FAM72C, SRGAP2D.
- chr4:68,509,441–68,670,652, 6 genes: UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr7:84,876,554–84,876,956, 1 gene: HMGN2P11.
- chr7:108,900,105–108,905,226, 1 gene: AC004014.2.
- chr9:21,966,929–21,967,751, 1 gene (within-gene range 0–1): CDKN2A-DT.
- chr21:7,744,962–8,701,562, 29 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 988 genes in 61 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,450,245, 3 genes, copy number 6: AC239859.5, RNA5SP533, AC239859.3.
- chr1:145,095,974–145,242,124, 6 genes, copy number 8: FAM72D, LINC01145, RNU1-153P, AC241585.2, AC241585.1, PPIAL4D.
- chr2:90,209,873–91,714,745, 14 genes, copy number 5–9: IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7, AC233266.1, AC233266.2, AC116050.1, LSP1P4, RNA5SP100, DRD5P1, AC027612.2.
- chr6:60,719,222–60,942,327, 5 genes, copy number 5: GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3.
- chr6:61,574,328–65,707,226, 30 genes, copy number 5–12 (within-gene range 1–12): MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1.
- chr6:67,210,408–69,867,236, 20 genes, copy number 8–13 (within-gene range 1–13): AL591004.1, AL365503.1, RNA5SP208, RNU6-280P, Y_RNA, AL713998.1, AL713998.3, AL713998.4, AL713998.2, AL646090.2, AL646090.1, AL593844.1, LINC02549, AL606923.2, AL606923.1, AL391807.1, ADGRB3, LMBRD1, NPM1P37, GAPDHP42.
- chr7:4,511,959–4,771,442, 3 genes, copy number 6–7: CYP3A54P, FOXK1, AC092428.1.
- chr7:5,879,827–6,939,603, 43 genes, copy number 6–7: OCM, CCZ1, RSPH10B, PMS2, Y_RNA, AIMP2, SNORA80D, EIF2AK1, ANKRD61, RN7SL851P, RNU6-218P, AC004895.1, USP42, CYTH3, Y_RNA, FAM220A, AC009412.1, RPSAP73, RAC1, DAGLB, KDELR2, AC072052.1, GRID2IP, ZDHHC4, AC079742.1, C7orf26, ZNF853, ZNF316, AC073343.2, AC073343.1, ZNF12, PMS2CL, SPDYE20P, RSPH10B2, CCZ1B, OR7E39P, UNC93B2, OR7E136P, OR7E59P, AC079804.2, ALG1L5P, AC079804.1, FAM86LP.
- chr7:8,113,184–8,344,516, 5 genes, copy number 5: ICA1, AC006042.1, AC007009.1, AC007128.1, AC007128.2.
- chr8:66,946,501–67,056,604, 3 genes, copy number 5 (within-gene range 4–5): TCF24, PPP1R42, AC110998.1.
- chr8:67,062,417–67,196,778, 3 genes, copy number 5 (within-gene range 2–5): CSPP1, RNA5SP268, AC087359.1.
- chr9:66,635,754–66,932,141, 7 genes, copy number 5–7: RBPJP2, RAB28P4, ATP5F1AP10, SDR42E1P4, FKBP4P8, ZNF658, BX664608.1.
- chr9:67,791,499–68,330,626, 10 genes, copy number 5–10 (within-gene range 4–10): RN7SL787P, SNORA70, AL627230.2, ANKRD20A1, RNU6-368P, AL353608.2, CBWD3, AL353608.4, AL353608.3, AL353608.1.
- chr10:16,071,416–16,295,858, 3 genes, copy number 5: FTLP19, RNU6-1075P, LINC02654.
- chr10:38,356,380–38,783,108, 14 genes, copy number 9: HSD17B7P2, SEPTIN7P9, AL133216.2, RNU6-1118P, CICP9, AL133216.1, ABCD1P2, AL133173.2, PABPC1P12, SLC9B1P3, ACTR3BP5, CHEK2P5, AL133173.1, AL590623.1.
- chr11:3,591,277–3,826,371, 12 genes, copy number 5–7: AP006294.1, OR7E117P, TRPC2, ART5, ART1, Y_RNA, Y_RNA, CHRNA10, NUP98, RNU6-1143P, RNU7-50P, PGAP2.
- chr11:8,011,278–8,169,055, 6 genes, copy number 5–6: CASC23, TUB, AC116456.1, TUB-AS1, AC116456.2, RIC3.
- chr11:56,971,050–58,181,616, 57 genes, copy number 5: OR5AK3P, OR5AK2, OR5AK1P, OR5BQ1P, OR5AK4P, OR5AO1P, OR5BP1P, LRRC55, APLNR, TNKS1BP1, AP000781.1, SSRP1, P2RX3, PRG3, PRG2, AP000781.2, SLC43A3, RNA5SP341, RN7SKP259, RTN4RL2, AP002893.1, SLC43A1, RN7SL605P, TIMM10, SMTNL1, UBE2L6, RPS4XP13, SERPING1, AP000662.1, MIR130A, YPEL4, CLP1, ZDHHC5, MED19, AP001931.2, TMX2, PPIAP42, SELENOH, AP001931.1, BTBD18, CTNND1, OR5BA1P, AP003484.1, OR5AZ1P, OR5BD1P, CYCSP26, OR9Q1, RNU6-899P, OR6Q1, VN2R9P, AP004247.2, AP004247.1, OR9L1P, OR9I3P, OR9I1, OR9I2P, OR5BL1P.
- chr11:68,870,664–72,843,674, 143 genes, copy number 7 (within-gene range 1–7) (broad region; genes not listed).
- chr11:73,214,998–78,582,156, 176 genes, copy number 7–26 (broad region; genes not listed).
- chr11:79,604,967–80,957,634, 8 genes, copy number 14–25: AP001978.1, AP001541.1, AP001284.1, AP006295.1, RNU6-544P, ARL6IP1P3, LINC02720, AP003398.1.
- chr11:88,050,106–88,098,147, 2 genes, copy number 6: AP005436.3, AP005436.1.
- chr12:6,786,858–10,454,685, 197 genes, copy number 6 (broad region; genes not listed).
- chr12:10,551,266–10,572,688, 2 genes, copy number 6: SLC25A39P2, LINC02446.
- chr12:11,507,162–11,895,377, 7 genes, copy number 6: AC007450.3, DDX55P1, AC007450.2, AC007450.1, RNU7-60P, LINC01252, ETV6.
- chr12:12,289,227–12,471,233, 6 genes, copy number 6: RNU6-318P, MANSC1, RPL23AP66, LOH12CR2, BORCS5, AC007619.2.
- chr12:14,169,746–14,365,503, 7 genes, copy number 6–7: AC092470.1, AC135001.1, AC092112.1, MRPS18CP4, RNU6-491P, GNAI2P1, RPL30P11.
- chr12:27,710,822–27,803,040, 5 genes, copy number 6 (within-gene range 4–6): MRPS35, Y_RNA, MANSC4, AC009511.2, KLHL42.
- chr12:69,239,569–69,274,358, 2 genes, copy number 6: CPSF6, MIR1279.
- chr14:18,333,726–19,714,332, 69 genes, copy number 6 (broad region; genes not listed).
- chr14:106,723,574–106,762,588, 2 genes, copy number 5: IGHV2-70D, IGHV1-69D.
- chr16:33,094,204–33,496,093, 16 genes, copy number 6 (within-gene range 3–6): HERC2P8, AC145350.4, AC145350.1, ABHD17AP9, AC138869.1, AC138869.2, TP53TG3C, AC138869.3, AC141257.2, TP53TG3E, AC141257.3, TP53TG3B, AC141257.1, AC141257.4, TP53TG3F, AC136944.5.
- chr16:34,120,470–34,163,110, 7 genes, copy number 6: AC136932.1, DUX4L45, PCMTD1P2, DUX4L46, DUX4L47, LINC00273, RNA5-8SP2.
- chr16:34,941,977–34,979,844, 2 genes, copy number 6: AC135776.4, LINC02184.
- chr17:59,106,598–59,155,260, 5 genes, copy number 5 (within-gene range 4–5): AC099850.1, SKA2, RNU2-58P, MIR454, MIR301A.
- chr17:60,256,720–60,666,280, 12 genes, copy number 5: AC104763.2, H3P42, C17orf64, RPL12P38, APPBP2, AC011921.3, AC011921.1, AC011921.2, LINC01999, RPSAP66, PPM1D, RNU6-623P.
- chr17:67,774,591–67,785,293, 2 genes, copy number 5: RPSAP67, RPL17P41.
- chr18:10,724,619–10,908,783, 3 genes, copy number 5: KIAA0895LP1, MIR6788, AP005120.1.
- chr21:13,038,160–13,120,807, 4 genes, copy number 5: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr22:15,282,557–16,574,637, 42 genes, copy number 5: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2, YME1L1P1, OR11H1, AP000534.2, ARHGAP42P3, AP000534.1, AP000533.2, AP000533.1, AP000533.3, AP000532.2, NEK2P2, AP000532.1, NF1P6, MED15P7, POTEH, POTEH-AS1, RNU6-816P, AP000529.1, PSLNR, GRAMD4P2, DUXAP8, AP000526.1, BMS1P22, AP000525.1, DUXAP8, NBEAP3, TOMM40P2, AP000522.1, AC145543.1, U6, ABCD1P4, AC137499.1, PABPC1P9, SLC9B1P4, ACTR3BP6, CHEK2P4, AP000547.2, AP000547.1.

Autosomal genes at a single copy (total copy number 1): 16,827. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
